Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A60J, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A60J-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Oligoastrocytoma NOS
9382/3
Site CCF Supratentorial NOS
C71.0
path L Brain, frontal lobe
C71.1
W 4/16/13

Study ID:

Patient Age/Sex / F

SPECIMEN SUBMITTED:

Part A: LEFT FRONTAL BRAIN MASS

Part B: LEFT FRONTAL BRAIN TUMOR

Final Diagnosis

Left frontal lobe, excision (A & B) - Low-grade mixed glioma (low-grade oligoastrocytoma), WHO grade II.

Diagnosis Comment:

The tumor is marked by geographically distinct areas resembling low grade astrocytoma and low grade oligodendroglioma. Vascular proliferative changes and necrosis are not seen.

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Excision

Specimen handling: Frozen and permanent sections

Site: Frontal lobe

Laterality: Left

Diagnosis: Low-grade mixed glioma (low-grade oligoastrocytoma)

WHO Grade: II

Ancillary test(s) ordered: P53, Ki-67, and IDH-1 (R132H) immunostains; 1p, 19q, and EGFR FISH

Procedure: ADDENDUM

Status: Signed Out

Text: Immunohistochemical staining of the tumor (block B2) with antibodies to IDH1 (R132H), Ki-67, and p53 was performed. The tumor demonstrates diffuse positive staining with IDH1. A Ki-67 labeling index of 11-12% is focally noted. Greater than 50% of the tumor cells demonstrate positive staining with antibody to p53.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the
The U.S. Food
and Drug Administration has not approved or cleared this test; however, FDA clearance
or approval is not currently required for clinical use.

ICPAA Discrepancy		

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Procedure: FISH for 1p/19q

Status: Signed Out

Text:

1p/19q FISH RESULTS

RESULTS

Chromosome 1p: Intact, aneusomic
Chromosome 19q: Intact, aneusomic

Quantitative FISH results:

1p36: 3.4

1q25: 3.2

1p36/1q25 ratio: 1.1

19q13: 3.4

19p13: 3.0

19q13/19p13 ratio: 1.1

SPECIMEN SUBMITTED: Paraffin block B2

INTERPRETATION

1p intact: A majority of nuclei showed similar numbers of 1p36 and 1q25 signals. There is no evidence of allelic loss on the short arm of chromosome 1 (1p).

19q intact: A majority of nuclei showed similar numbers of 19q13 and 19p13 signals. There is no evidence of allelic loss of 19q.

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneuploidy for chromosome 1 and 19 may be associated with earlier recurrence. References: Cairncross et al J Natl Cancer Inst 90:1473-1479, 1998; Smith et al, J Clin Oncol 18:636-645, 2000; Ino et al, J Neurosurg 92:983-990, 2000; Schmidt et al, J Neuropathol Exp Neurol 61:321-328, 2002; Snuderl et al, ClinCancer Res 15:6430-7, 2009.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13)

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the Pathology and Laboratory Medicine. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block B2

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes

The following FISH results were obtained:

EGFR 2.8

CEP7 2.7

EGFR/CEP7 ratio 1.0

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas (Smith JS, et al., J Natl Canc Inst 93:1246-1256, 2001; Ino et al., J Neurosurgery 92:983-990 2000).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma

Clinical Diagnosis:

LEFT FRONTAL BRAIN TUMOR

Gross Description:

A. Received fresh on gauze for frozen consultation labeled "left frontal brain mass" are two fragments of white-tan tissue aggregating to 0.5 x 0.2 x 0.1 cm. Half of the specimen is submitted as FSA1. The remainder of the specimen is totally submitted for permanent evaluation as A2.

B. Received fresh labeled "left frontal brain tumor" are three irregular shaped segments of tan-white soft and rubbery tissue aggregating to 2.5 x 2.0 x 2.0 cm and weighing 6.9 grams. Upon sectioning, a tan-white mottled, smooth and glistening cut surface is identified. The segments are totally submitted in formalin in B1-B3.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 80690b63-3ba8-4918-870d-332087f808c5 (TCGA-FG-A60J.0EE45912-9058-4883-922E-1B788D3A7A68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).